Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6167, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6167-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:
Colon cancer.

Specimens Submitted:
1: SP:colon, Right ; resection

DIAGNOSIS:

1. SP:colon, Right ; resection:
Tumor Type:

Adenocarcinoma

Histologic Grade:

Poorly differentiated
with signet ring cells

Tumor Location:

Cecum

Tumor Size:

Length is 8.5 cm

Width is 7.0 cm

Maximal thickness is 1.1 cm

Tumor Budding:

Extensive

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubulovillous adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

extensive.

Large Venous Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Tubulo-villous adenoma; number: 3

** Continued on next page **

[page 2 of 3]
Non-Neoplastic Bowel:

Unremarkable

Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 11

Total number examined: 40

Tumor deposits in pericorectal soft tissue:

Identified

Identified; number:3

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N2b (Metastasis in seven or more regional lymph nodes)

NOTE: IMMUNOHISTOCHEMICAL STAINS SHOW THAT THE TUMOR CELLS ARE POSITIVE FOR CK20, CDX2, AND VERY FOCALLY POSITIVE FOR CK7, WHILE NEGATIVE FOR SYNAPTOPHYSIN, CHROMOGRANIN, ER AND PR. THE RESULTS ARE CONSISTENT WITH A PRIMARY COLON CARCINOMA.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

1. The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 11.5 cm in length and 3.3 cm in circumference at the proximal resected margin. The remaining colon measures 46 cm in length with a circumference of 7.5 cm at the distal resected margin. The attached appendix measures 5 cm in length and averages 0.8 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally

** Continued on next page **

[page 3 of 3]
hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 2.0 cm in thickness. The specimen is opened to reveal a partially fungating and partially infiltrating lesion measuring 8.5 cm in length and 7 cm in width. The mass is located in the cecum, 11.5 cm from the proximal margin and 39 cm from the distal margin. Sectioning shows that the tumor invades possibly subserosal fibroadipose tissue. The depth of invasion is 1.1 cm grossly. The remaining mucosa shows 3 polyps measuring 0.2 to 2.5 cm in greatest dimension. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave
D - distal margin shave
T - tumor
A - appendix representative sections
RSC - representative sections of colon
RSI - representative sections of ilium
POY - polyps, representatives
LP - largest polyp, serial sections
LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:

Part 1: SP:colon, Right ; resection

Block	Sect. Site	PCs
2	a	2
1	d	1
12	LN	24
2	lp	2
1	p	1
2	poy	2
2	rsc	2
2	rsi	2
10	t	10

** End of Report **

Source: NCI Genomic Data Commons file 70fce709-f796-4a1b-adcf-777e3c1eee88 (TCGA-CM-6167.8A5176DA-E133-4647-B2BB-30285B8BBEAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).